Surgical pathology report (de-identified scan), TCGA case TCGA-VN-A88P, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-VN-A88P-01A (Primary Tumor).

[page 1 of 4]
Gender: Male	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
CASE NUMBER:	Final
DIAGNOSIS:	

1. Prostate, prostatectomy:
- Adenocarcinoma, Gleason grade predominant pattern 7 (3+4) with a component of 8 (4+4) involving 60% of the left lobe and 25% of the right.
- Perineural invasion present.
- No extracapsular or seminal vesicles invasion seen.
- Tumor approaches focally the left margin anteriorly.
2. Lymph node, fat over anterior prostate, resection: Fibroadipose tissue. Lymph node, no tumor seen (0/1).
3. Inguinal node, right obturator packet, excision: Fibroadipose tissue. Lymph nodes, no tumor seen (0/10).
4. Lymph node, right external iliac packet, excision: Fibroadipose tissue. Lymph nodes, no tumor seen (0/6).
5. Lymph node, right internal iliac packet, excision: Fibroadipose tissue. Lymph nodes, no tumor seen (0/22).
6. Lymph node, left obturator, packet, excision: Fibroadipose tissue. Lymph nodes, no tumor seen (0/7).
7. Lymph node, left external iliac packet, excision: Fibroadipose tissue. Lymph node, no tumor seen (0/1).
8. Lymph node, left internal iliac packet, excision: Fibroadipose tissue. Lymph nodes, no tumor seen (0/18).

ICD-0.3
Adenocarcinoma, acinar
Site: Prostate NOS
8146/3
C61.9
Jp) 12/12/13

NOTE:

CAP Cancer Protocol:
PROSTATE GLAND: Radical Prostatectomy

Procedure
Radical prostatectomy
Prostate Size
Weight: 41.6 g
Size: 5.0 x 4.7 x 4.0 cm

Lymph Node Sampling
Pelvic lymph node dissection

Histologic Type
Adenocarcinoma (acinar, not otherwise specified)
Histologic Grade
Gleason Pattern

[page 2 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
---------------------------	----------------------

Primary Pattern
Grade 4

Secondary Pattern
Grade 4

Total Gleason Score: 8

Tumor Quantitation
Proportion (percentage) of prostate involved by tumor: up to 60%

Extraprostatic Extension
Not identified
Seminal Vesicle Invasion
Not identified

Margins
Approaching the black ink margin (left side).

Treatment Effect on Carcinoma
Not identified

Lymph-Vascular Invasion
Not identified

+ Perineural Invasion
+ Present

Pathologic Staging (pTNM)

Primary Tumor (pT)

+ pT2c: Bilateral disease

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Number of Lymph Nodes Examined
Specify: 65

Number of Lymph Nodes Involved
Specify: 0

Distant Metastasis (pM)
Not applicable

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the
They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: M with G1 8 prostate cancer Specimen Taken
For Protocol: Yes Allocate Order to Protocol:

[page 3 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
--------------------	---------------

PROCEDURE: Pre-Operative Diagnosis: prostate cancer Post-Operative
Diagnosis:
prostate cancer Operative Findings: see dictation

- SPECIMENS SUBMITTED: 1. PROSTATE
2. LYMPH NODES, Fat over anterior prostate
3. OBTURATOR LYMPH NODE(S), Right
4. INGUINAL NODE(S), Right external packet
5. INGUINAL NODE(S), Right internal packet
6. OBTURATOR LYMPH NODE(S), Left packet
7. INGUINAL NODE(S), Left external packet
8. INGUINAL NODE(S), Left internal packet

GROSS DESCRIPTION: Received in Surgical Pathology are fresh 8 containers labeled with the patient's name and medical record number and further specified as follows:

1. "Prostate" consists of prostatectomy specimen weighing 41.6 grams with the following measurements:

Left-right: 4.7
Anterior-posterior: 4
Apex-base: 5.0
Left seminal vesicles: 4.8 x 2.2 x 0.8 cm
Left vas deferens: 4.8 cm in length x 0.6 cm in diameter
Right seminal vesicles: 4.6 x 1.2 x 0.9 cm.
Right vas deferens : 4.7 cm in length x 0.7 cm in diameter

The prostate is inked as follows: Urethra in yellow, anterior 1/3 in black, right posterior 2/3 in blue, and left posterior 2/3 in red. Gross photographs are taken. One cut is made revealing a tan soft nodular cut surface and ill-defined firm nodular foci 2 cm in greatest dimensions, positioned in through left mid base anteriorly. Approximately 0.9 x 0.6 x 0.4 cm of tissue from the left mid base nodule and approximately 0.5 x 0.5 x 0.4 cm of normal-appearing prostatic tissue from the right anterior aspect are procured for the by and document by on at Received in is a specimen matching the above description. It is serially sectioned using custom fabricated from apex to base. Summary of sections is as follows:
1A-G: Serially sectioned prostate, entirely submitted.
1H-1K: Left seminal vesicles plus vas deferens, entirely submitted
1L-O: Right seminal vesicles and vas deferens, entirely submitted

2. "Fat and lymph node over anterior prostate". It consists of fibrofatty tissue measuring in aggregate 2.5 x 2.5 x 1.5 cm. It is palpated for candidate lymph nodes. Three candidate are found and submitted in white cassette labeled The remainder of the palpated fat is submitted entirely in white cassettes labeled

[page 4 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Location:

Surgical Pathology	Final Results
--------------------	---------------

3. "Right obturator lymph node packet" consists of fibrofatty tissue measuring in aggregate 2.5 x 2.8 x 2 cm. It is palpated for candidate lymph nodes. No candidate lymph nodes are found, and the palpated tissue is entirely submitted in white cassette labeled

4. "Right external iliac". It consists of fibrofatty tissue measuring in aggregate 3 x 3 1.7 cm. It is palpated for candidate lymph nodes. Six candidate lymph nodes are found and submitted in cassette #4A and #4B. The remainder of the palpated specimen is placed entirely in cassettes E.

5. "Right internal iliac lymph node packet". It consists of fibrofatty tissue measuring in aggregate 2.5 x 2.5 x 1.5 cm. The specimen is palpated for candidate lymph nodes and 2 candidate lymph nodes are found submitted in a white cassette labeled . The remainder of the palpated tissue is submitted in white cassette labeled 5D.

6. "Left obturator lymph node packet" consists of fibrofatty tissue, yellow-tan, measuring 2.5 x 2.5 x 1.5 cm. It palpated for candidate lymph nodes. Five candidate lymph nodes are found and placed in cassettes and 6B. The remainder of the fibrofatty tissue is placed entirely in cassette .

7. "Left external iliac lymph node" consists of fibrofatty tissue measuring in aggregate 1.5 x 1.5 x 1.3cm. It is palpated for candidate lymph nodes. Two candidate lymph nodes are found and placed in a white cassette labeled . The remainder of the palpated tissue is entirely submitted in cassettes labeled B and 7C.

8. "Left internal iliac lymph node packet" consists of fibrofatty tissue measuring in aggregate 1.5 x 1.5 x 1 cm. It palpated for candidate lymph nodes. Three candidate lymph nodes are found and placed in white cassette labeled 8B. The remainder of the palpated tissue is entirely placed in white cassettes labeled 8D.

Gross Description dictated by

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Criteria	10/22/13	Yes	No
Dual/Synchronous Primary	Noted		

Source: NCI Genomic Data Commons file 1b70ba89-776c-4ff7-9b79-3c683a68dc29 (TCGA-VN-A88P.9C83DFB8-B75A-40D1-B791-BE52B52BBDA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).